Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6883, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6883-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 6

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Multiple organ resection – Segment of the large intestine**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectosigmoid junction**

Examination performed on:

Macroscopic description:

A 18.6 cm length of the large intestine with fat tissue of 2 cm in thickness. A button-like tumour , sized 3.7 x 4.5 x 1.2 cm found in the mucosa. The lesion surrounds 90% of the intestine circumference, is located 1.1 cm from one of the incision lines and 12 cm from the other one. Minimum margin 2.1 cm

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltrado carcinomatosa telae adiposae mesorecti

Incision lines clear of neoplastic lesions.

Lymphonodulitis reactiva No XVI.

Histopathological diagnosis:

Adenocarcinoma tubulare recti. Tubular adenocarcinoma of the rectum.

(G2, Dukes B, Astler-Coller B2, pT3, pNO, R0).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 70cb32be-a2d2-4ae1-86af-778716c51754 (TCGA-EI-6883.4C1D1EEC-CCEE-458E-8A30-5EF519D0BB46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).